CCDI case PBCVAU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/661f7a2e-d295-4028-bd44-cb682b3ea0d8

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E0HQN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0HR0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
